Somatic mutation profile of tumor specimen TCGA-85-A50M-01A (aliquot TCGA-85-A50M-01A-21D-A25L-08) from TCGA case TCGA-85-A50M, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.7 years (17,429 days).
Specimen TCGA-85-A50M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11ff9e56-cb4b-42a6-aadb-dd97cd9e6eed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A50M-10A (Blood Derived Normal), aliquot TCGA-85-A50M-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50992033-02d7-4c5b-a333-aa2df345677e

The open-access MAF lists 92 somatic variants for this specimen: 61 protein-altering or splice-affecting, 29 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 29, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Frame Shift Ins 1, 3'UTR 1, In Frame Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 18/50 reads (36%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 39/115 reads (34%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.173); catalogued as COSV99791972; called by muse, mutect2, varscan2
- ABL1 | c.3020C>G p.S1007* | Nonsense Mutation (SNP) | VAF 10/104 reads (10%) | catalogued as COSV100583826; called by muse, mutect2
- ADCY2 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100602558, COSV57867675; called by muse, mutect2, varscan2
- BRWD1 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60897624; called by muse, mutect2, varscan2
- CD38 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.796); catalogued as COSV99882579; called by muse, mutect2, varscan2
- CDH9 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.174); catalogued as COSV99143436; called by muse, mutect2, varscan2
- CHD5 | c.2260G>T p.V754F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52411960, COSV99313328; called by muse, mutect2, varscan2
- CHGB | c.1227G>T p.R409S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV100972946; called by muse, mutect2, varscan2
- DDX3X | c.796C>A p.P266T (on ENST00000399959; = p.P267T on NM_001356.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV101302413, COSV67864407; called by muse, mutect2, varscan2
- DYNC2I1 | c.2621A>T p.N874I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV101337655; called by muse, mutect2, varscan2
- EPB41L4B | c.2168A>C p.N723T | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100775842; called by muse, mutect2
- EPB42 | c.385C>T p.L129F (on ENST00000441366 / NM_001114134.2; = p.L159F on NM_000119.3) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100281914; called by muse, mutect2
- FBXO34 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV100571909; called by muse, mutect2
- FRMD3 | c.95T>C p.M32T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100418538; called by muse, mutect2
- HCN1 | c.1997C>A p.P666Q | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.86); catalogued as COSV100299771, COSV57492798, COSV57541621; called by muse, mutect2, varscan2
- HS6ST1 | c.729C>G p.Y243* | Nonsense Mutation (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99389506; called by muse, mutect2, varscan2
- HTR3A | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55469055; called by muse, mutect2
- HTR5A | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as rs758761162, COSV55284225; called by muse, mutect2, varscan2
- IGSF22 | c.1754T>A p.F585Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100079555; called by muse, mutect2, varscan2
- IRAG2 | c.3648C>A p.H1216Q (on ENST00000636465; = p.H261Q on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100611705, COSV100611768; called by muse, mutect2, varscan2
- ITPR1 | c.7330A>T p.T2444S (on ENST00000354582; = p.T2389S on NM_002222.7) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100230746, COSV57000094; called by muse, mutect2, varscan2
- LILRB4 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV99553732; called by muse, mutect2, varscan2
- LIX1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99172899; called by muse, mutect2, varscan2
- LPIN1 | c.1723G>C p.A575P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99877415; called by muse, mutect2, varscan2
- MTTP | c.2262G>T p.Q754H | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99645028; called by muse, mutect2, varscan2
- MYH4 | c.2269C>A p.H757N | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV99701017; called by muse, mutect2, varscan2
- MYO7A | c.5639A>G p.N1880S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.98); catalogued as COSV68684219; called by muse, mutect2
- MYPN | c.2156G>T p.S719I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100589864; called by muse, mutect2
- NEDD4L | c.1767G>T p.P589= (on ENST00000400345 / NM_001144967.3; = p.P569= on NM_015277.6) | Splice Region (SNP) | VAF 5/53 reads (9%) | catalogued as COSV56846144, COSV99894442; called by muse, mutect2
- NETO2 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs971571891, COSV57453188; called by muse, mutect2, varscan2
- NLRP3 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 16/123 reads (13%) | catalogued as COSV100275810; called by muse, mutect2, varscan2
- OGN | c.462G>C p.L154F | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.902); catalogued as COSV99364052; called by muse, mutect2
- PBX1 | c.511-2A>T p.X171_splice | Splice Site (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100905030, COSV63348818; called by muse, mutect2, varscan2
- PLCXD3 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV100125586, COSV100126632; called by muse, mutect2
- PLXNA4 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149257060, COSV58103872, COSV58133382; called by muse, mutect2, varscan2
- RCAN2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV100149548; called by muse, mutect2, varscan2
- RYR2 | c.9673G>A p.G3225S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs780484631, COSV100769347, COSV100769564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.2105C>T p.T702M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1197830058, COSV73306477; called by muse, mutect2, varscan2
- SNRPB | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100293285; called by muse, mutect2, varscan2
- SSTR4 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV54796687, COSV99658529; called by muse, mutect2
- STPG2 | c.1034T>G p.V345G | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV99758917; called by muse, varscan2
- THOP1 | c.91C>G p.Q31E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100310505; called by muse, mutect2, varscan2
- TIGD7 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV51915356, COSV51916772; called by muse, mutect2
- TMX3 | c.141+1G>C p.X47_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100218313; called by muse, mutect2, varscan2
- TP53INP2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs763974095, COSV100873682; called by muse, mutect2
- WDR53 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs778792411, COSV100218055; called by muse, mutect2, varscan2
- ZMAT2 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.558); catalogued as COSV99218046; called by muse, mutect2, varscan2
- ZNF148 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs867728901, COSV100642053; called by muse, mutect2, varscan2
- ZNF536 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as COSV100835073; called by muse, mutect2, varscan2
- APLP2 | c.135dup p.A46Cfs*4 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAPKAPK3 | c.1033del p.D345Tfs*5 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.1145del p.N382Tfs*10 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- PPP1R15B | c.1857_1876del p.C619* | Nonsense Mutation (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- RGS1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2
- UNC45B | c.2469_2471dup p.A825dup | In Frame Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel
- VPS26B | c.338A>G p.E113G | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZBED4 | c.3011_3020del p.F1004Cfs*23 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- AC098582.1 | c.945C>A p.L315= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99985500; called by muse, mutect2, varscan2
- AKAP6 | c.5136G>A p.P1712= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs375264170; called by muse, mutect2
- ANK2 | c.11574C>A p.T3858= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100000997; called by muse, mutect2, varscan2
- APOC3 | c.288C>A p.A96= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs144573427; called by muse, mutect2, varscan2
- CDH12 | c.2319C>A p.P773= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV66421586; called by muse, mutect2, varscan2
- CIRBP | c.189C>T p.A63= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs777298813, COSV100309757; called by muse, mutect2, varscan2
- CUX1 | c.1317G>A p.L439= (on ENST00000437600 / NM_181500.4; = p.L441= on NM_001913.5) | Silent (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CYLC1 | c.483T>C p.T161= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100254477; called by muse, mutect2, varscan2
- DNAH1 | c.7884C>T p.V2628= | Silent (SNP) | VAF 7/113 reads (6%) | catalogued as COSV101325529; called by muse, mutect2
- DSG1 | c.2418C>T p.T806= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV57137063, COSV99935850; called by muse, mutect2, varscan2
- FCRL5 | c.1980C>A p.I660= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100708810, COSV100709378, COSV62515073; called by muse, mutect2, varscan2
- FEZF2 | c.519C>T p.N173= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1559836982, COSV99334656; called by muse, mutect2
- GCLC | c.957G>A p.L319= (on ENST00000643939; = p.L317= on NM_001498.4) | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV99988545; called by muse, mutect2
- GP5 | c.1125G>T p.L375= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1305870855, COSV100540807; called by muse, mutect2
- IL16 | c.3933T>C p.P1311= (on ENST00000302987 / NM_172217.5; = p.P610= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100250803; called by muse, mutect2, varscan2
- KLHL31 | c.471G>A p.K157= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100911764; called by muse, mutect2, varscan2
- LDB2 | c.909A>G p.G303= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV100453391; called by muse, mutect2
- MBD5 | c.2682G>A p.Q894= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV101290040; called by muse, mutect2
- MDN1 | c.9183C>T p.L3061= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101021176; called by muse, mutect2
- OR5H14 | c.81G>T p.L27= | Silent (SNP) | VAF 24/241 reads (10%) | catalogued as COSV101454149; called by muse, mutect2, varscan2
- PCDHA2 | c.2004G>A p.S668= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as rs369554786; called by muse, mutect2, varscan2
- PNPLA5 | c.606C>A p.P202= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV99336596; called by muse, mutect2, varscan2
- PRIM2 | c.63C>A p.S21= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99227956; called by muse, mutect2, varscan2
- RPP25L | c.117G>T p.L39= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs368641365; called by muse, mutect2, varscan2
- RYR2 | c.1023G>T p.G341= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100769563; called by muse, mutect2, varscan2
- SERPINA3 | c.579A>T p.T193= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV101261672; called by muse, mutect2, varscan2
- SOCS5 | c.1218G>A p.R406= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100125061; called by muse, mutect2
- TAS1R1 | c.2436C>T p.C812= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1435367563, COSV100039619; called by muse, mutect2, varscan2
- UNC5B | c.390C>T p.C130= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1486046568, COSV100101139; called by muse, mutect2
- COL18A1-AS1 | n.1569T>C | RNA (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101181705; called by muse, mutect2, varscan2
- NGB | c.*312G>T | 3'UTR (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100030051; called by muse, mutect2, varscan2
